CCDI case PBBMSY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5fd9ac5d-2864-47d6-8a76-bbf94041e726

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.5 years (906 days).

Biospecimens (3 samples)
- Sample 0DCM17: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCM1F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCM1K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
